Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGG, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGG-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; nonseminoma (MT + IT 90%, EC 5%, YST 5%, trophoblastic giant cells);
diameter 5.5 cm; tumor confined to testis; no angio-invasion present; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O-3

Germ cell tumor, mixed
908513

Site: ① Testis NOS
C629

JA 3/7/14

Criteria	lw 1/18/14	Yes	No

Source: NCI Genomic Data Commons file d8f114dc-307f-4fb0-9755-9ee3a4a2c120 (TCGA-2G-AAGG.58657E09-72D7-4D8D-8739-78AFD708EDF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).